Surgical pathology report (de-identified scan), TCGA case TCGA-CI-6624, project TCGA-READ (Rectum Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-CI-6624-01C (Primary Tumor).

Collection Date: [REDACTED]

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Rectal mass.

PROCEDURE: Flexible sigmoidoscopy with biopsy.

SPECIFIC CLINICAL QUESTION: Cancer.

OUTSIDE TISSUE DIAGNOSIS: No.

PRIOR MALIGNANCY: No.

CHEMORADIATION: No.

ORGAN TRANSPLANT: No.

IMMUNOSUPPRESSION: No.

OTHER DISEASES: No.

TCGA - CI - 6624

FINAL DIAGNOSIS:

RECTUM, MASS, BIOPSY -

INVASIVE ADENOCARCINOMA (See comment).

COMMENT:

Multiple tissue levels have been examined.

Source: NCI Genomic Data Commons file 1a3581e1-3ef6-42bd-b818-c082091cb7e2 (TCGA-CI-6624.7DA84C10-2A8D-4876-97B7-D5BEF4D3884F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).